Gene-level copy-number profile of tumor specimen TCGA-49-AAR9-01A from TCGA case TCGA-49-AAR9, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 61.6 years (22,510 days).
Specimen TCGA-49-AAR9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.b80ed025-61e3-47a1-aec6-9195605ada66.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-49-AAR9-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f84161d9-fd6c-46ae-8e74-f78a6be14ca9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 13,255; copy number 3: 2,487; copy number 4: 30,052; copy number 5: 1,800; copy number 6: 8,909; copy number 7: 1,578; copy number 8: 1,059; copy number 9: 205; copy number 10: 106; copy number 11: 66; copy number 12: 122; copy number 13: 41; copy number 15: 73; copy number 36: 25; copy number 45: 3; copy number 48: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-49-AAR9-01A-21D-A40Z-01): tumor purity 0.75, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 664 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:26,243,170–26,395,891, 4 genes, copy number 13 (within-gene range 6–13): HADHB, AC010896.1, ADGRF3, SELENOI.
- chr2:27,427,790–27,988,087, 18 genes, copy number 11: NRBP1, KRTCAP3, IFT172, AC074117.2, RNU6-986P, FNDC4, GCKR, C2orf16, ZNF512, AC074091.2, CCDC121, GPN1, AC074091.1, SUPT7L, SLC4A1AP, LINC01460, MRPL33, RBKS.
- chr2:27,896,116–28,016,482, 3 genes, copy number 11: MYG1P1, MIR4263, FAM133EP.
- chr2:43,230,836–43,838,865, 10 genes, copy number 11 (within-gene range 6–11): THADA, RNU6-958P, RN7SL531P, Y_RNA, PLEKHH2, C1GALT1C1L, AC011242.1, RN7SKP66, DYNC2LI1, ABCG5.
- chr2:48,809,340–49,419,013, 1 gene, copy number 9 (within-gene range 6–9): AC009975.1.
- chr2:48,962,157–49,888,986, 7 genes, copy number 9 (within-gene range 6–9): FSHR, MIR548BA, AC009975.2, RNU6-439P, AC009971.1, RPL7P13, SNORA75.
- chr2:51,032,601–57,380,132, 79 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr3:63,741,827–66,388,116, 36 genes, copy number 9–10 (within-gene range 8–10): AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1, ADAMTS9-AS2, LINC02040, MAGI1, AC121493.1, ILF2P1, RPL17P17, MAGI1-IT1, MAGI1-AS1, Y_RNA, AC106827.1, SLC25A26, RNU6-787P, RN7SL482P.
- chr5:7,065,091–7,069,351, 1 gene, copy number 9 (within-gene range 6–9): AC025756.1.
- chr5:42,188,266–45,895,970, 62 genes, copy number 9 (broad region; genes not listed).
- chr6:8,158,162–8,760,447, 1 gene, copy number 9 (within-gene range 6–9): AL355499.2.
- chr6:8,411,435–9,294,133, 3 genes, copy number 9 (within-gene range 4–9): SLC35B3, HULC, AL161437.1.
- chr6:53,561,289–54,485,850, 15 genes, copy number 11 (within-gene range 8–11): AL033397.1, LINC01564, KLHL31, AL590652.1, LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1, CLNS1AP1.
- chr6:63,193,072–63,779,336, 16 genes, copy number 9: AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 9: AL354719.1, SCAT8, GCNT1P4.
- chr8:49,086,301–49,907,446, 8 genes, copy number 9 (within-gene range 6–9): AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1.
- chr8:53,225,724–55,081,909, 35 genes, copy number 13: OPRK1, AC131902.1, AC022034.3, AC131902.2, AC022034.1, AC022034.4, AC022034.2, MAPK6P1, AC103778.1, ATP6V1H, RGS20, AC113194.1, RPS27AP13, RNU6-1331P, TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1, RNU105C, AC027250.1, AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7, RP1, SEC11B, AC090151.1, AC084834.1.
- chr8:55,135,203–55,164,727, 2 genes, copy number 13: AC022679.2, AC022679.1.
- chr8:57,994,509–59,456,010, 20 genes, copy number 11: FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2, UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1, TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1, RNA5SP267.
- chr12:21,536,203–34,249,958, 246 genes, copy number 12–48 (within-gene range 4–48) (broad region; genes not listed).
- chr17:81,681,174–83,095,122, 94 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
